Somatic mutation profile of tumor specimen TCGA-AA-A029-01A (aliquot TCGA-AA-A029-01A-01W-A00E-09) from TCGA case TCGA-AA-A029, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Cecum; AJCC pathologic stage: Stage II; Age at diagnosis: 67.6 years (24,686 days).
Specimen TCGA-AA-A029-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) badf5858-3314-4fba-98ab-27d05fb2670e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AA-A029-10A (Blood Derived Normal), aliquot TCGA-AA-A029-10A-01W-A00E-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e9e9c2e4-9fa6-449b-92fb-f97448088c5a

The open-access MAF lists 94 somatic variants for this specimen: 69 protein-altering or splice-affecting, 20 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 55, Silent 20, Frame Shift Del 5, Nonsense Mutation 5, RNA 3, Splice Site 2, In Frame Ins 1, Frame Shift Ins 1, 5'UTR 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.2804dup p.Y935* | Nonsense Mutation (INS) | VAF 72/192 reads (38%) | hotspot (GDC flag); catalogued as rs863225332, CI023287, CI991958, COSV57344655; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- ATP1A2 | c.2563G>A p.G855R | Missense Mutation (SNP) | VAF 35/77 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.625); catalogued as rs1553245857, CM096627, COSV63404569; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 21/25 reads (84%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- SMAD2 | c.962G>A p.R321Q | Missense Mutation (SNP) | VAF 69/122 reads (57%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV50994862; called by muse, mutect2, varscan2
- TGFBR2 | c.1570G>A p.D524N | Missense Mutation (SNP) | VAF 29/56 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs727504421, CM064328, CM139809, COSV55448438, COSV55452463; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCA13 | c.14362G>A p.V4788M | Missense Mutation (SNP) | VAF 19/38 reads (50%) | SIFT tolerated (0.48); PolyPhen benign (0.294); catalogued as rs373171750; called by muse, mutect2, varscan2
- ACTL9 | c.992G>A p.R331H | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as rs781963592, COSV61005716; called by muse, mutect2, varscan2
- ACVR1B | c.1003G>A p.D335N | Missense Mutation (SNP) | VAF 72/75 reads (96%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57778154; called by muse, mutect2, varscan2
- ACVRL1 | c.1147G>A p.E383K | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as rs148057374; called by muse, mutect2, varscan2
- ANK3 | c.12420del p.K4140Nfs*15 (on ENST00000280772 / NM_001320874.2; = p.K661Nfs*15 on NM_001149.3) | Frame Shift Del (DEL) | VAF 22/213 reads (10%) | catalogued as rs1466658148; called by mutect2, pindel, varscan2
- APC | c.4364del p.N1455Ifs*18 | Frame Shift Del (DEL) | VAF 76/247 reads (31%) | catalogued as CM080064, COSV57320740, COSV57379025; called by mutect2, pindel, varscan2
- APPL2 | c.1978G>A p.A660T | Missense Mutation (SNP) | VAF 36/121 reads (30%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.001); catalogued as rs367929771; called by muse, mutect2, varscan2
- ARHGAP21 | c.1763C>G p.P588R | Missense Mutation (SNP) | VAF 186/421 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.421); catalogued as COSV57607675; called by muse, mutect2, varscan2
- CADPS | c.2516G>A p.R839H | Missense Mutation (SNP) | VAF 76/217 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.039); catalogued as rs184805711, COSV51866742; called by muse, mutect2, varscan2
- CCDC114 | c.1604C>T p.T535I | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT deleterious (0.04); PolyPhen benign (0.036); catalogued as rs764834353, COSV59555131, COSV59557374; called by muse, mutect2, varscan2
- CCDC171 | c.2891C>T p.P964L | Missense Mutation (SNP) | VAF 33/110 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.964); catalogued as COSV52645256; called by muse, mutect2, varscan2
- CCZ1 | c.194G>A p.C65Y | Missense Mutation (SNP) | VAF 33/109 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV58074461; called by muse, mutect2, varscan2
- CD300C | c.383A>T p.E128V | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT tolerated (0.34); PolyPhen benign (0.113); catalogued as COSV58170842; called by muse, mutect2, varscan2
- CDH2 | c.2669G>T p.W890L | Missense Mutation (SNP) | VAF 85/207 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52285564; called by muse, mutect2, varscan2
- CNKSR3 | c.1387C>T p.R463W | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1325726838, COSV70481263; called by muse, mutect2
- COL6A6 | c.1950C>A p.S650R | Missense Mutation (SNP) | VAF 50/136 reads (37%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.494); catalogued as COSV62018829; called by muse, mutect2, varscan2
- CREBBP | c.4021C>T p.R1341* | Nonsense Mutation (SNP) | VAF 15/18 reads (83%) | catalogued as CM131079, COSV52113887; called by muse, mutect2, varscan2
- CRHR2 | c.289C>A p.Q97K | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT tolerated (0.75); PolyPhen benign (0.044); catalogued as COSV59266148; called by muse, mutect2, varscan2
- DGKH | c.843G>T p.W281C | Missense Mutation (SNP) | VAF 16/511 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99819041; called by muse, mutect2
- DHX29 | c.1444A>G p.M482V | Missense Mutation (SNP) | VAF 130/292 reads (45%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV52419308; called by muse, mutect2, varscan2
- DLL1 | c.671C>T p.P224L | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.169); catalogued as rs751267284, COSV64537232; called by muse, mutect2, varscan2
- DNAH5 | c.5081A>T p.D1694V | Missense Mutation (SNP) | VAF 72/135 reads (53%) | SIFT deleterious (0); PolyPhen benign (0.027); catalogued as COSV54235944; called by muse, mutect2, varscan2
- DNAH5 | c.869G>A p.W290* | Nonsense Mutation (SNP) | VAF 103/355 reads (29%) | catalogued as COSV54235953; called by muse, mutect2, varscan2
- DOCK8 | c.4886+1G>A p.X1629_splice | Splice Site (SNP) | VAF 15/42 reads (36%) | catalogued as COSV66621365; called by muse, mutect2, varscan2
- ENPP2 | c.2131+1G>A p.X711_splice (on ENST00000075322 / NM_001040092.3; = p.X763_splice on NM_006209.5) | Splice Site (SNP) | VAF 85/283 reads (30%) | catalogued as rs988184026, COSV50012594, COSV50023704; called by muse, mutect2, varscan2
- EXOC6 | c.586T>A p.S196T | Missense Mutation (SNP) | VAF 150/384 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.142); catalogued as COSV53327321; called by muse, mutect2, varscan2
- FAM155A | c.785G>T p.R262M | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.891); catalogued as COSV65569965; called by muse, mutect2, varscan2
- FAT3 | c.4819G>A p.A1607T | Missense Mutation (SNP) | VAF 69/117 reads (59%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.661); catalogued as COSV53134717; called by muse, mutect2, varscan2
- FMO5 | c.191C>T p.S64F | Missense Mutation (SNP) | VAF 246/432 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54208186; called by muse, mutect2, varscan2
- GTF2IRD2B | c.1760C>T p.T587M | Missense Mutation (SNP) | VAF 6/107 reads (6%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.991); catalogued as rs782203730, COSV57032905; called by muse, mutect2
- HFM1 | c.3140C>T p.T1047M | Missense Mutation (SNP) | VAF 52/172 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs754765102, COSV54029040; called by muse, mutect2, varscan2
- HS3ST3B1 | c.623G>A p.R208Q | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT tolerated (0.11); PolyPhen benign (0.018); catalogued as COSV62906656; called by muse, mutect2
- HTRA1 | c.769G>T p.D257Y | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT tolerated (0.06); PolyPhen benign (0.127); catalogued as COSV64564601; called by muse, mutect2, varscan2
- KDM5A | c.3710C>T p.P1237L | Missense Mutation (SNP) | VAF 79/319 reads (25%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.986); catalogued as COSV66993880; called by muse, mutect2, varscan2
- LHCGR | c.1646T>G p.I549S | Missense Mutation (SNP) | VAF 170/485 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54299236; called by muse, varscan2
- LIG4 | c.313G>C p.D105H | Missense Mutation (SNP) | VAF 12/126 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV63597411; called by muse, mutect2
- MUC17 | c.11445A>T p.L3815F | Missense Mutation (SNP) | VAF 38/112 reads (34%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.777); catalogued as COSV60293960; called by muse, mutect2, varscan2
- MYH11 | c.4775G>A p.R1592K | Missense Mutation (SNP) | VAF 29/29 reads (100%) | SIFT tolerated (0.65); PolyPhen benign (0.028); catalogued as rs1237673081, COSV55558812; called by muse, mutect2, varscan2
- NOL8 | c.1355_1358del p.H452Pfs*13 | Frame Shift Del (DEL) | VAF 75/238 reads (32%) | catalogued as rs1319337157; called by mutect2, pindel, varscan2
- OR14A16 | c.277C>A p.L93I | Missense Mutation (SNP) | VAF 49/382 reads (13%) | SIFT tolerated (0.29); PolyPhen benign (0.168); catalogued as COSV62926939; called by muse, mutect2, varscan2
- OR2T6 | c.763G>T p.A255S | Missense Mutation (SNP) | VAF 38/78 reads (49%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.646); catalogued as COSV63216618; called by muse, mutect2, varscan2
- PCDH11Y | c.1649G>A p.R550H (on ENST00000400457 / NM_032973.2; = p.R539H on NM_032971.3) | Missense Mutation (SNP) | VAF 9/83 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.231); catalogued as rs755672059, COSV53084157; called by muse, mutect2, varscan2
- PKHD1 | c.2276C>T p.A759V | Missense Mutation (SNP) | VAF 25/77 reads (32%) | SIFT tolerated (0.81); PolyPhen benign (0.023); catalogued as COSV61883342; called by muse, mutect2, varscan2
- PLCZ1 | c.175G>T p.E59* | Nonsense Mutation (SNP) | VAF 43/260 reads (17%) | catalogued as COSV56855252; called by muse, mutect2, varscan2
- PPFIA2 | c.3188T>G p.L1063* | Nonsense Mutation (SNP) | VAF 45/211 reads (21%) | catalogued as COSV61039847; called by muse, mutect2, varscan2
- PPP2R3A | c.1984G>A p.E662K | Missense Mutation (SNP) | VAF 118/275 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as COSV53866628; called by muse, mutect2, varscan2
- PRAMEF20 | c.1399G>A p.D467N | Missense Mutation (SNP) | VAF 105/244 reads (43%) | SIFT tolerated (0.24); PolyPhen benign (0.435); catalogued as rs1016857044; called by muse, mutect2, varscan2
- PYGO1 | c.1045G>A p.E349K | Missense Mutation (SNP) | VAF 174/439 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs748090860, COSV57348492; called by muse, mutect2, varscan2
- RSBN1 | c.1991G>A p.R664H | Missense Mutation (SNP) | VAF 73/154 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.142); catalogued as rs1353087249, COSV54731558; called by muse, mutect2, varscan2
- SLFN11 | c.355C>T p.R119C | Missense Mutation (SNP) | VAF 85/200 reads (43%) | SIFT tolerated (0.05); PolyPhen benign (0.11); catalogued as rs751102443, COSV57699408; called by muse, mutect2, varscan2
- SRGAP3 | c.1936G>A p.D646N | Missense Mutation (SNP) | VAF 35/96 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.452); catalogued as COSV64535605; called by muse, mutect2, varscan2
- TRPV4 | c.1465G>A p.A489T | Missense Mutation (SNP) | VAF 8/9 reads (89%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); catalogued as rs758280554, COSV55681421; ClinVar: benign / uncertain significance; called by muse, mutect2, varscan2
- TTN | c.6358C>T p.R2120W (on ENST00000591111; = p.R2074W on NM_003319.4) | Missense Mutation (SNP) | VAF 178/207 reads (86%) | PolyPhen probably damaging (0.96); catalogued as rs116158152, COSV59904099; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- UACA | c.3209_3212del p.K1070Sfs*2 | Frame Shift Del (DEL) | VAF 208/598 reads (35%) | catalogued as rs760248027; called by pindel, varscan2
- ZNF329 | c.844A>C p.T282P | Missense Mutation (SNP) | VAF 62/233 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as COSV63772835; called by muse, mutect2, varscan2
- ZSCAN5A | c.1097C>T p.T366M | Missense Mutation (SNP) | VAF 58/98 reads (59%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.454); catalogued as rs1200016620, COSV54224212; called by muse, mutect2, varscan2
- AK9 | c.5570dup p.Y1858Vfs*2 | Frame Shift Ins (INS) | VAF 59/169 reads (35%) | called by mutect2, pindel, varscan2
- CSMD1 | c.3529A>C p.N1177H (on ENST00000520002; = p.N1176H on NM_033225.6) | Missense Mutation (SNP) | VAF 87/126 reads (69%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.639); called by muse, varscan2
- LRP1B | c.11567A>G p.H3856R | Missense Mutation (SNP) | VAF 22/356 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.119); called by muse, mutect2
- POLR2J | c.134T>C p.I45T | Missense Mutation (SNP) | VAF 6/305 reads (2%) | SIFT deleterious (0.02); PolyPhen benign (0.243); called by muse, mutect2
- PPP2R3A | c.2317G>A p.E773K | Missense Mutation (SNP) | VAF 17/30 reads (57%) | SIFT deleterious (0.03); PolyPhen benign (0.16); called by muse, mutect2, varscan2
- RYR2 | c.8073del p.K2691Nfs*66 | Frame Shift Del (DEL) | VAF 5/34 reads (15%) | called by mutect2, pindel, varscan2
- SLC13A5 | c.1552G>A p.G518R | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- WDR49 | c.1017_1019dup p.L340dup (on ENST00000308378 / NM_001366158.1; = p.L681dup on NM_001348951.2 and 2 other RefSeq transcripts) | In Frame Ins (INS) | VAF 65/164 reads (40%) | called by mutect2, pindel, varscan2
- ABCF2 | c.1557C>T p.D519= | Silent (SNP) | VAF 16/31 reads (52%) | catalogued as rs545658338, COSV55184157; called by muse, mutect2
- AOPEP | c.1227G>A p.T409= | Silent (SNP) | VAF 16/238 reads (7%) | catalogued as rs563351486; called by muse, mutect2
- BDNF | c.483C>T p.G161= | Silent (SNP) | VAF 44/124 reads (35%) | catalogued as rs376008850, COSV59236312; called by muse, mutect2, varscan2
- BMPER | c.2031C>A p.I677= | Silent (SNP) | VAF 22/274 reads (8%) | catalogued as COSV51823674; called by muse, mutect2
- BRWD3 | c.4944C>A p.T1648= | Silent (SNP) | VAF 284/345 reads (82%) | catalogued as COSV64750256; called by muse, mutect2, varscan2
- C1orf87 | c.1185G>A p.L395= | Silent (SNP) | VAF 142/366 reads (39%) | catalogued as rs765248043, COSV64597613; called by muse, varscan2
- DHX34 | c.1740A>G p.L580= | Silent (SNP) | VAF 4/10 reads (40%) | catalogued as rs754715456, COSV60894644; called by muse, mutect2
- DHX40 | c.129G>A p.T43= | Silent (SNP) | VAF 6/55 reads (11%) | catalogued as rs750016821, COSV52068557; called by muse, mutect2, varscan2
- ELAVL3 | c.630G>A p.T210= | Silent (SNP) | VAF 7/20 reads (35%) | catalogued as rs144875735, COSV63646727; called by muse, mutect2, varscan2
- MEGF8 | c.2007G>A p.T669= | Silent (SNP) | VAF 5/23 reads (22%) | catalogued as rs779109120, COSV52091360; called by muse, mutect2, varscan2
- MORF4L2 | c.255C>T p.N85= | Silent (SNP) | VAF 87/99 reads (88%) | catalogued as rs1242277512, COSV64610973; called by muse, mutect2, varscan2
- MYO18B | c.6849G>A p.T2283= | Silent (SNP) | VAF 8/15 reads (53%) | catalogued as rs771862908, COSV59139391; called by muse, mutect2, varscan2
- PHACTR1 | c.390C>T p.S130= | Silent (SNP) | VAF 17/37 reads (46%) | catalogued as rs1210915045, COSV60672079; called by muse, mutect2, varscan2
- PRAMEF8 | c.825C>T p.S275= | Silent (SNP) | VAF 8/19 reads (42%) | catalogued as rs1452320836; called by mutect2, varscan2
- RPS6KA2 | c.1569C>A p.L523= | Silent (SNP) | VAF 17/128 reads (13%) | catalogued as rs772464934, COSV55823598; called by muse, mutect2
- SCN2A | c.126G>A p.K42= | Silent (SNP) | VAF 109/125 reads (87%) | catalogued as COSV51836917, COSV51846681; called by muse, mutect2, varscan2
- SGCZ | c.585G>A p.T195= | Silent (SNP) | VAF 21/76 reads (28%) | catalogued as rs550319628, COSV66023667; called by muse, mutect2, varscan2
- TSGA10 | c.567C>T p.T189= | Silent (SNP) | VAF 189/225 reads (84%) | catalogued as rs201138854, COSV61824006; called by muse, mutect2, varscan2
- TTI2 | c.1251T>G p.T417= | Silent (SNP) | VAF 32/95 reads (34%) | catalogued as COSV62452986; called by muse, mutect2, varscan2
- ZNF114 | c.1200G>A p.S400= | Silent (SNP) | VAF 46/131 reads (35%) | catalogued as rs926698131, COSV59944319; called by muse, mutect2, varscan2
- CCNQP1 | n.88C>A | RNA (SNP) | VAF 27/82 reads (33%) | called by muse, mutect2, varscan2
- CHCHD2P9 | n.249del | RNA (DEL) | VAF 8/29 reads (28%) | called by mutect2, varscan2
- CHD8 | c.5051+495A>G | Intron (SNP) | VAF 27/61 reads (44%) | called by muse, mutect2, varscan2
- FAM74A3 | n.144G>T | RNA (SNP) | VAF 10/138 reads (7%) | called by muse, mutect2
- TNFRSF19 | c.-1G>T | 5'UTR (SNP) | VAF 13/28 reads (46%) | catalogued as COSV99947284; called by muse, mutect2, varscan2
